CPTAC case C3L-00017 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d0a4a77b-3676-490b-9058-22509098cb27

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1946; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 69.4 years (25,349 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Residual disease: RX; Days to last known disease status: 426 days (1.2 years); Days to last follow up: 426 days (1.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.5 cm (a second GDC size field records 1.5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 42; Lymphatic invasion present: No; Margin status: Involved; Perineural invasion present: Yes; Vascular invasion present: No.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 426.

Other clinical attributes
- Weight: 84.09 kg; Height: 172.2 cm; BMI: 28.36; Comorbidities: Hyperlipidemia.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Tobacco smoking quit year: 2016; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (7 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00017-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 260 mg.
- Sample C3L-00017-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 230 mg; Time between excision and freezing: 27 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00017-22: Section location: Head; Percent tumor nuclei: 20; Percent necrosis: 0.
- Sample C3L-00017-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 210 mg.
- Sample C3L-00017-04: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 530 mg; Time between excision and freezing: 29 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00017-05: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 520 mg.
- Sample C3L-00017-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 580 mg.
- Sample C3L-00017-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
